EXCEPTIONAL_RESPONDERS case ER-B0GE — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Rectum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/571a2208-ab6a-45f4-aeca-11dbcbf0cc94

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Year of birth: 1968; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 44.8 years (16,378 days); Year of diagnosis: 2013; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,357 days (3.7 years); Days to best overall response: 777 days (2.1 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Capecitabine; Days to treatment start: 354 days; Days to treatment end: 643 days (1.8 years).
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 445 days (1.2 years); Days to treatment end: 578 days (1.6 years).

Follow-up (1 entry)
- Days to follow up: 1,357 days (3.7 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,357 days (3.7 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0GE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0GE-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
